Somatic mutation profile of cancer-model specimen HCM-BROD-0112-C25-85A (3D Organoid, passage 5; aliquot HCM-BROD-0112-C25-85A-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0112-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 76.6 years (27,984 days).
Specimen HCM-BROD-0112-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37faa182-7bfd-4150-9737-c976a0762f97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0112-C25-10B (Blood Derived Normal), aliquot HCM-BROD-0112-C25-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5ee21e1-fa54-42be-9730-c9acdbe2416d

The open-access MAF lists 88 somatic variants for this specimen: 68 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 58, Silent 20, Nonsense Mutation 4, Splice Region 3, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 163/361 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 223/223 reads (100%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 104/233 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs369863403, COSV100900208; called by muse, mutect2, varscan2
- ADAM18 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 144/217 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV99695354; called by muse, mutect2, varscan2
- ADAMTS16 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 158/338 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs752370037; called by muse, mutect2, varscan2
- C10orf71 | c.2599G>A p.V867I | Missense Mutation (SNP) | VAF 149/333 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs373861853, COSV60506335; called by muse, mutect2, varscan2
- CDH23 | c.3851C>T p.S1284L | Missense Mutation (SNP) | VAF 118/276 reads (43%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs1410108291, COSV56466547; called by muse, mutect2, varscan2
- CFAP74 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 229/365 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs767951086; called by muse, mutect2, varscan2
- DHCR7 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 184/398 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.626); catalogued as rs201466849, CM129944; called by muse, mutect2, varscan2
- ESS2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 110/371 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs370053001; called by muse, mutect2, varscan2
- FGF13 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV59551012; called by muse, mutect2, varscan2
- FRAS1 | c.9374A>G p.H3125R | Missense Mutation (SNP) | VAF 222/340 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs958448008; called by muse, mutect2, varscan2
- HSP90AB1 | c.1648A>G p.K550E | Missense Mutation (SNP) | VAF 230/349 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as rs139414975; called by muse, mutect2, varscan2
- KRTAP20-4 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 109/247 reads (44%) | PolyPhen probably damaging (0.98); catalogued as COSV58169155; called by muse, mutect2, varscan2
- LAMB4 | c.3915G>A p.A1305= | Splice Region (SNP) | VAF 94/221 reads (43%) | catalogued as rs756445994, COSV52727753; called by muse, mutect2, varscan2
- LRIG1 | c.2668G>A p.V890I | Missense Mutation (SNP) | VAF 141/365 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs767414411, COSV56237373; called by muse, mutect2, varscan2
- MAGEA1 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 289/367 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV63118261; called by muse, mutect2, varscan2
- MYH4 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs765014025, COSV55118122; called by muse, mutect2, varscan2
- MYO18B | c.6772C>T p.R2258W | Missense Mutation (SNP) | VAF 114/430 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368571524, COSV59151680; called by muse, mutect2, varscan2
- MYOM3 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 106/426 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs753559533; called by muse, mutect2
- NAA16 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 159/161 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1351968246; called by muse, mutect2, varscan2
- PEAR1 | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 255/452 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs201663935, COSV52773745; called by muse, mutect2, varscan2
- PMFBP1 | c.1965G>A p.T655= (on ENST00000537465; = p.T650= on NM_031293.3) | Splice Region (SNP) | VAF 31/133 reads (23%) | catalogued as rs1419638729, COSV52821037; called by muse, mutect2, varscan2
- PXDN | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 86/485 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as rs749632473; called by muse, mutect2, varscan2
- RIMS1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 192/296 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV99327316; called by muse, mutect2, varscan2
- SMAD4 | c.1138A>G p.R380G | Missense Mutation (SNP) | VAF 112/112 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV61687236, COSV61690485; called by muse, mutect2, varscan2
- STAB1 | c.2854C>T p.R952W | Missense Mutation (SNP) | VAF 276/597 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs375779383; called by muse, mutect2, varscan2
- TEKT3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777321677; called by muse, mutect2, varscan2
- TENM2 | c.6625G>A p.G2209R (on ENST00000518659 / NM_001122679.2; = p.G1970R on NM_001080428.3) | Missense Mutation (SNP) | VAF 273/548 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756812300, COSV69133581; called by muse, mutect2, varscan2
- TRBV28 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 138/347 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs750139882; called by muse, mutect2, varscan2
- TRIM71 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 435/902 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.303); catalogued as COSV101070418; called by muse, mutect2, varscan2
- UBE2O | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 190/823 reads (23%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); catalogued as COSV51685041; called by muse, mutect2, varscan2
- ZC3H13 | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.073); catalogued as rs1383213121, COSV54465179; called by muse, mutect2, varscan2
- ZNF37A | c.1276C>T p.L426F | Missense Mutation (SNP) | VAF 101/192 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV100697312; called by muse, mutect2, varscan2
- ABRAXAS2 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 68/133 reads (51%) | called by muse, mutect2, varscan2
- BMP4 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 213/872 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMPR1A | c.1216C>A p.R406S | Missense Mutation (SNP) | VAF 126/237 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBLL1 | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 92/166 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CC2D1B | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 198/296 reads (67%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, varscan2
- CCDC85A | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 44/1066 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CDKN2A | c.233_234del p.L78Hfs*41 | Frame Shift Del (DEL) | VAF 196/708 reads (28%) | called by pindel, varscan2
- CHRD | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 338/674 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL1A1 | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 211/693 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CST3 | c.40A>T p.I14F | Missense Mutation (SNP) | VAF 371/736 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0); called by mutect2, varscan2
- DMD | c.5572C>T p.H1858Y | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DONSON | c.113A>G p.E38G | Missense Mutation (SNP) | VAF 237/526 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMN2 | c.3436C>G p.L1146V | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.202); called by muse, varscan2
- GALNT2 | c.209C>A p.T70N | Missense Mutation (SNP) | VAF 137/247 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GBGT1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 355/557 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GSDMC | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 102/314 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- HHATL | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 148/346 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV3D-11 | c.290G>T p.S97I | Missense Mutation (SNP) | VAF 134/539 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- KIAA1109 | c.14453A>C p.D4818A | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MAP2K7 | c.105_109del p.S35Rfs*55 | Frame Shift Del (DEL) | VAF 126/133 reads (95%) | called by mutect2, pindel, varscan2
- MBOAT2 | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 26/546 reads (5%) | called by muse, mutect2
- MOCS3 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 172/780 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO9B | c.4481C>G p.S1494* | Nonsense Mutation (SNP) | VAF 204/541 reads (38%) | called by muse, mutect2, varscan2
- NDUFAF2 | c.127+6G>T | Splice Region (SNP) | VAF 20/428 reads (5%) | called by muse, mutect2
- PRDM8 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 170/517 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- SEPTIN8 | c.1025A>G p.E342G | Missense Mutation (SNP) | VAF 111/564 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- TBR1 | c.1426C>A p.P476T | Missense Mutation (SNP) | VAF 265/1034 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- THSD7B | c.4286G>T p.G1429V (on ENST00000272643; = p.G1427V on NM_001316349.2) | Missense Mutation (SNP) | VAF 178/379 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC30A | c.1331A>G p.E444G | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC30B | c.1331A>G p.E444G | Missense Mutation (SNP) | VAF 187/890 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.38968G>T p.A12990S (on ENST00000591111; = p.A5566S on NM_003319.4) | Missense Mutation (SNP) | VAF 280/590 reads (47%) | PolyPhen benign (0.061); called by muse, mutect2, varscan2
- WNK1 | c.6751C>T p.H2251Y (on ENST00000315939 / NM_018979.4; = p.H2003Y on NM_014823.3) | Missense Mutation (SNP) | VAF 251/552 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF16 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 144/417 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF730 | c.780del p.K260Nfs*101 | Frame Shift Del (DEL) | VAF 177/460 reads (38%) | called by mutect2, pindel, varscan2
- ANO7 | c.1905C>T p.G635= (on ENST00000274979; = p.G581= on NM_001370694.2) | Silent (SNP) | VAF 97/493 reads (20%) | called by muse, mutect2, varscan2
- CPAMD8 | c.5160C>T p.A1720= (on ENST00000651564; = p.A1673= on NM_015692.5) | Silent (SNP) | VAF 38/762 reads (5%) | called by muse, mutect2
- CSF1R | c.1659C>T p.I553= | Silent (SNP) | VAF 133/334 reads (40%) | catalogued as rs372747391, COSV53834768; called by muse, mutect2, varscan2
- CSMD1 | c.6717C>T p.S2239= (on ENST00000520002; = p.S2238= on NM_033225.6) | Silent (SNP) | VAF 89/337 reads (26%) | catalogued as rs369976310; called by muse, mutect2, varscan2
- FIGN | c.1140G>A p.K380= | Silent (SNP) | VAF 163/669 reads (24%) | catalogued as rs949148554; called by muse, mutect2, varscan2
- FLNA | c.2952C>T p.D984= | Silent (SNP) | VAF 289/369 reads (78%) | catalogued as rs782513930, COSV61046051; called by muse, mutect2, varscan2
- GCKR | c.1671C>T p.I557= | Silent (SNP) | VAF 133/521 reads (26%) | called by muse, mutect2, varscan2
- H1-1 | c.225C>T p.D75= | Silent (SNP) | VAF 41/412 reads (10%) | catalogued as rs1561912734; called by muse, mutect2, varscan2
- KLF18 | c.1464G>A p.G488= | Silent (SNP) | VAF 68/655 reads (10%) | catalogued as rs1458329216; called by muse, mutect2, varscan2
- LRRC56 | c.390C>T p.D130= | Silent (SNP) | VAF 22/701 reads (3%) | called by muse, mutect2
- MNX1 | c.738C>T p.T246= | Silent (SNP) | VAF 161/492 reads (33%) | called by muse, mutect2, varscan2
- NUP210L | c.2817C>T p.T939= | Silent (SNP) | VAF 42/404 reads (10%) | called by muse, mutect2
- OLIG3 | c.321C>T p.R107= | Silent (SNP) | VAF 73/577 reads (13%) | catalogued as rs1487922443, COSV62988597; called by muse, mutect2, varscan2
- OR1R1P | c.241C>T p.L81= | Silent (SNP) | VAF 316/317 reads (100%) | called by muse, mutect2, varscan2
- PAPPA | c.3351C>T p.T1117= | Silent (SNP) | VAF 38/296 reads (13%) | called by muse, mutect2, varscan2
- SOX8 | c.633G>A p.G211= | Silent (SNP) | VAF 221/225 reads (98%) | called by muse, mutect2, varscan2
- SPART | c.393T>A p.S131= | Silent (SNP) | VAF 262/262 reads (100%) | called by muse, mutect2, varscan2
- USP51 | c.426G>A p.P142= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as COSV72351481; called by muse, mutect2, varscan2
- ZNF764 | c.762C>T p.T254= | Silent (SNP) | VAF 209/446 reads (47%) | catalogued as rs1271568307; called by muse, mutect2, varscan2
- ZSWIM9 | c.579C>T p.P193= | Silent (SNP) | VAF 129/332 reads (39%) | catalogued as rs1423288064; called by muse, mutect2, varscan2
